Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012419-09A.1 (aliquot TARGET-15-SJMPAL012419-09A.1-01D) from TARGET case TARGET-15-SJMPAL012419, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.4 years (5,973 days).
Specimen TARGET-15-SJMPAL012419-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac126eb9-5c49-401c-95d0-0c6a30f0ee7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012419-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012419-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b31178b-0b59-43ae-894c-769b1b194788

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, RNA 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXTL1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375730801; called by muse, mutect2, varscan2
- GAGE2A | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 41/358 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs5906821, COSV62995474, COSV62995723; called by muse, varscan2
- MUC4 | c.11991C>G p.H3997Q | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.065); catalogued as rs113130007, COSV57770630; called by muse, varscan2
- PCDHA10 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 113/214 reads (53%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs782288464, COSV100253124; called by muse, mutect2, varscan2
- RNF20 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV66355722; called by muse, mutect2, varscan2
- SEL1L | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs374625468; called by muse, mutect2, varscan2
- BRF1 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2
- GRK3 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- N4BP1 | c.1751A>C p.D584A | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- XBP1 | c.508_509insCGGC p.R170Pfs*218 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | called by mutect2, pindel
- CASP1 | c.831G>A p.P277= (on ENST00000436863 / NM_033292.4; = p.P256= on NM_001223.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/151 reads (48%) | catalogued as rs1456744063, COSV62056501; called by muse, mutect2, varscan2
- IGLV5-45 | c.303C>T p.L101= | Silent (SNP) | VAF 55/202 reads (27%) | called by muse, mutect2, varscan2
- NAT10 | c.840T>C p.V280= | Silent (SNP) | VAF 62/106 reads (58%) | called by muse, mutect2, varscan2
- USP13 | c.2301C>T p.H767= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1299829596; called by muse, mutect2, varscan2
- ACTR3BP2 | n.803T>C | RNA (SNP) | VAF 26/215 reads (12%) | catalogued as rs1911780; called by muse, mutect2
- AL669831.1 | n.2639G>C | RNA (SNP) | VAF 10/71 reads (14%) | catalogued as rs369817233; called by mutect2, varscan2
- ANGPTL3 | c.-30C>T | 5'UTR (SNP) | VAF 36/85 reads (42%) | catalogued as rs769920975; called by muse, mutect2, varscan2
